CCDI case PBBXUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c5b736d2-cc2d-49c7-a9e5-c6f3a17b62fc

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (547 days).

Biospecimens (3 samples)
- Sample 0DLJWD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLJWL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLJX2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
